Somatic mutation profile of tumor specimen 0DSYEC from CCDI case PBCITR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Dermatofibrosarcoma protuberans, NOS; Tissue or organ of origin: Skin of trunk; Age at diagnosis: 8.3 years (3,021 days).
Specimen 0DSYEC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecd11646-92cc-4257-be8c-f1a650c95ed0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSYEA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fe756d4-78f4-43ab-9f86-73b26e2f39e7

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN10A | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 66/617 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1294999278, COSV71861574; called by muse, varscan2
